Somatic mutation profile of tumor specimen 0DNMAO from CCDI case PBBYZN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.8 years (6,509 days).
Specimen 0DNMAO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9e4001c-1e4b-432a-9847-3d909ca4fbaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNM9V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/771a59dc-4d0a-4081-904e-8c6df1306017

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 46/207 reads (22%) | called by muse, mutect2, varscan2
- MARCKSL1 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- POP4 | c.389T>A p.L130H | Missense Mutation (SNP) | VAF 35/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEX13D | c.153G>A p.Q51= | Silent (SNP) | VAF 20/203 reads (10%) | called by muse, mutect2, varscan2
- EXOC7 | c.1582+35C>G | Intron (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2, varscan2
